Somatic mutation profile of tumor specimen MP2PRT-PASWGG-TMP1-A (aliquot MP2PRT-PASWGG-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWGG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,062 days).
Specimen MP2PRT-PASWGG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb9d27a1-81dd-4970-8364-50b52603adbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWGG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWGG-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7da741a6-2058-40dc-a9e8-a571690fcc59

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 39/135 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 56/388 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AK9 | c.5030C>G p.S1677C | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746816252, COSV69850091; called by muse, mutect2, varscan2
- DOP1B | c.3644G>A p.R1215Q | Missense Mutation (SNP) | VAF 30/476 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs995184007, COSV101215726; called by muse, mutect2
- HK2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs911955878; called by muse, mutect2, varscan2
- KCNA10 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373944479; called by muse, varscan2
- KIF14 | c.3136C>T p.R1046C | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs752380834, COSV66264306; called by muse, mutect2, varscan2
- KLHL32 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs1167755041; called by muse, mutect2, varscan2
- NOS1 | c.1760G>A p.C587Y | Missense Mutation (SNP) | VAF 114/457 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57625345; called by muse, mutect2, varscan2
- XKR6 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 162/360 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs571870939; called by muse, mutect2, varscan2
- CNKSR3 | c.249_250insGGCCCCAAG p.N83_L84insGPK | In Frame Ins (INS) | VAF 34/237 reads (14%) | called by mutect2, pindel, varscan2
- DBN1 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MEF2B | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 176/638 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SETD2 | c.7143dup p.S2382Lfs*47 | Frame Shift Ins (INS) | VAF 170/454 reads (37%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 92/678 reads (14%) | called by muse, mutect2, varscan2
- BCL11B | c.573C>T p.V191= | Silent (SNP) | VAF 27/663 reads (4%) | called by muse, mutect2
